Somatic mutation profile of tumor specimen TCGA-AA-3560-01A (aliquot TCGA-AA-3560-01A-01D-1953-10) from TCGA case TCGA-AA-3560, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 72.2 years (26,359 days).
Specimen TCGA-AA-3560-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a719a4b9-e7d0-4e89-a62e-9f4b741b00a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3560-10A (Blood Derived Normal), aliquot TCGA-AA-3560-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147c007c-af86-49db-8c4b-568ea0c176ad

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.1817G>C p.S606T | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs775584015, COSV101063176; called by muse, mutect2, varscan2
- CFAP251 | c.870C>G p.N290K | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV99996074; called by muse, mutect2, varscan2
- CTNNA2 | c.1544A>C p.N515T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); catalogued as COSV100560497; called by muse, mutect2, varscan2
- EPG5 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99957182; called by muse, mutect2, varscan2
- FAM181A | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99967874; called by muse, mutect2, varscan2
- FCGR2C | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 30/39 reads (77%) | catalogued as COSV100912760; called by muse, mutect2, varscan2
- FEZF2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV51863369; called by muse, mutect2, varscan2
- GREB1 | c.4346G>A p.R1449Q | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs371972292, COSV52199653; called by muse, mutect2, varscan2
- NAV3 | c.4837T>A p.L1613M | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99890461; called by muse, mutect2, varscan2
- NT5C1A | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99348416; called by muse, mutect2, varscan2
- NUDCD3 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.448); catalogued as rs569119981, COSV100819336; called by muse, mutect2, varscan2
- NYX | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV100699369, COSV100699409; called by muse, mutect2, varscan2
- SOX11 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100431067; called by muse, mutect2, varscan2
- SOX4 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99782008; called by muse, mutect2, varscan2
- TRPM2 | c.3149A>G p.Y1050C | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100308740; called by muse, varscan2
- LSP1 | c.210G>A p.S70= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs768315651, COSV100289115; called by muse, varscan2
- OPRD1 | c.945C>T p.P315= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV99330276; called by muse, mutect2, varscan2
- PAX1 | c.723G>A p.P241= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1434161578, COSV68271351; called by muse, mutect2, varscan2
